Somatic mutation profile of tumor specimen TCGA-E1-A7YE-01A (aliquot TCGA-E1-A7YE-01A-11D-A34A-08) from TCGA case TCGA-E1-A7YE, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 32.8 years (11,971 days).
Specimen TCGA-E1-A7YE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f25a9ee-bb51-45fb-8182-31f6cad4e1e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7YE-10A (Blood Derived Normal), aliquot TCGA-E1-A7YE-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86fbc558-1da8-40a4-b2b0-0de3642fa7e9

The open-access MAF lists 80 somatic variants for this specimen: 57 protein-altering or splice-affecting, 17 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 17, Intron 4, Nonsense Mutation 2, Splice Site 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 37/87 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MED12 | c.131G>C p.G44A | Missense Mutation (SNP) | VAF 6/23 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199469672, COSV61329296, COSV61329353, COSV61329428; ClinVar: not provided; called by muse, mutect2, varscan2
- PIK3R1 | c.1746-1G>C p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 23/73 reads (32%) | hotspot (GDC flag); catalogued as COSV57125628, COSV57128950, COSV99163201; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 18/35 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- ACP3 | c.824C>G p.T275S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV60488675; called by muse, mutect2, varscan2
- ADAMTS9 | c.837G>C p.K279N | Missense Mutation (SNP) | VAF 85/211 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV55790866; called by muse, mutect2, varscan2
- ADGRE2 | c.1360A>G p.S454G | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV59696421; called by muse, mutect2, varscan2
- ADGRL3 | c.1187A>G p.E396G (on ENST00000506720 / NM_001322402.2; = p.E328G on NM_015236.6) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV72273595; called by muse, mutect2, varscan2
- AKAP8 | c.940C>G p.P314A | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV54104977; called by muse, mutect2, varscan2
- ARFGEF1 | c.4948G>C p.A1650P | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); catalogued as COSV51617140; called by muse, mutect2, varscan2
- ATRX | c.6565G>C p.V2189L | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64876906; called by muse, mutect2, varscan2
- CDC27 | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs765736331, COSV50680201; called by muse, mutect2, varscan2
- CDH24 | c.2100C>G p.I700M | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.246); catalogued as COSV57463618; called by muse, mutect2, varscan2
- DDX39B | c.44A>G p.D15G | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV58215173; called by muse, mutect2
- DYNC2H1 | c.7001C>T p.T2334I | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as rs745337448, COSV62107013; called by muse, mutect2, varscan2
- F8 | c.6499T>G p.Y2167D | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57706719; called by muse, mutect2, varscan2
- FAT4 | c.7709G>C p.R2570T | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV58709302; called by muse, mutect2, varscan2
- FAT4 | c.12706C>T p.R4236* | Nonsense Mutation (SNP) | VAF 12/105 reads (11%) | catalogued as rs942135672, COSV58694198; called by muse, mutect2, varscan2
- FCRL1 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV100839730, COSV100839879, COSV63827419; called by muse, mutect2, varscan2
- FLG | c.1438T>C p.S480P | Missense Mutation (SNP) | VAF 86/249 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100912009; called by muse, mutect2, varscan2
- FLT4 | c.3576G>C p.Q1192H | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV56122725; called by muse, mutect2, varscan2
- GATA3 | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV60522578; called by muse, mutect2, varscan2
- GLRB | c.539C>G p.T180S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV100029508, COSV52422617; called by muse, mutect2, varscan2
- GPRASP1 | c.3787C>T p.H1263Y | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs745890982, COSV64356485; called by muse, mutect2, varscan2
- GRIP1 | c.2294A>T p.K765M (on ENST00000359742 / NM_001379345.1; = p.K713M on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as COSV99670644; called by muse, mutect2, varscan2
- GTF2IRD1 | c.180G>C p.E60D | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV56092029; called by muse, mutect2, varscan2
- HTATSF1 | c.875G>C p.R292P | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV54481343; called by muse, mutect2, varscan2
- IL16 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV57268263; called by muse, mutect2, varscan2
- KCNG2 | c.562G>C p.A188P | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as COSV100302050; called by muse, mutect2, varscan2
- KRT1 | c.536G>C p.R179P | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs59044845, CM960908, COSV52869363; ClinVar: not provided; called by muse, mutect2, varscan2
- KRT28 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV60683553; called by muse, mutect2, varscan2
- LGI1 | c.1013T>A p.F338Y | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as CM1514142, COSV65059398; called by muse, mutect2, varscan2
- MATR3 | c.1706C>G p.S569C | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); catalogued as COSV63080094; called by muse, mutect2, varscan2
- MUC16 | c.20331G>C p.M6777I | Missense Mutation (SNP) | VAF 85/191 reads (45%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.188); catalogued as COSV67494905; called by muse, mutect2, varscan2
- MUC4 | c.15053G>C p.S5018T (on ENST00000463781 / NM_018406.7; = p.S782T on NM_004532.6) | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.054); catalogued as COSV57803549; called by muse, mutect2, varscan2
- MYH1 | c.1844C>T p.S615F | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV56857219; called by muse, mutect2, varscan2
- NECTIN3 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100162663; called by muse, mutect2, varscan2
- NEDD4 | c.1792G>C p.D598H (on ENST00000508342 / NM_001284338.1; = p.D179H on NM_006154.4) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV59066719; called by muse, mutect2, varscan2
- NFE2L2 | c.491C>G p.S164* | Nonsense Mutation (SNP) | VAF 32/47 reads (68%) | catalogued as COSV67962580; called by muse, mutect2, varscan2
- NFKBIA | c.38T>G p.M13R | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99395315; called by muse, mutect2, varscan2
- OIT3 | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1322310483, COSV100468296; called by muse, mutect2
- OR10G2 | c.620A>G p.D207G | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV73390474; called by muse, mutect2, varscan2
- OR2T10 | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs202004133, COSV100393788, COSV57897284; called by muse, mutect2
- ORC3 | c.1834-1G>C p.X612_splice | Splice Site (SNP) | VAF 38/83 reads (46%) | catalogued as COSV57643724; called by muse, mutect2, varscan2
- PCDHA7 | c.1067C>G p.S356C | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs782766094, COSV65347644; called by muse, mutect2, varscan2
- PDZRN4 | c.2037G>C p.E679D (on ENST00000402685 / NM_001164595.2; = p.E421D on NM_013377.4) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV54217676; called by muse, mutect2, varscan2
- PNMA3 | c.57G>T p.R19S | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV64722999; called by muse, mutect2, varscan2
- RGN | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100282537; called by muse, mutect2, varscan2
- SCN3A | c.3583C>G p.L1195V | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.529); catalogued as COSV51807473, COSV51824843; called by muse, mutect2, varscan2
- SLC15A2 | c.648C>G p.C216W | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55201002; called by muse, mutect2, varscan2
- SRRT | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 85/218 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs778413443, COSV61451384; called by muse, mutect2, varscan2
- SZT2 | c.4607C>G p.T1536S (on ENST00000634258 / NM_001365999.1; = p.T1479S on NM_015284.4) | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV65174693; called by muse, mutect2, varscan2
- TUBGCP2 | c.1043G>C p.G348A | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.241); catalogued as COSV53308932; called by muse, mutect2, varscan2
- UGT2A3 | c.108G>T p.W36C | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52359385, COSV99280171; called by muse, mutect2, varscan2
- ZWINT | c.613A>C p.K205Q | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.392); catalogued as COSV100571551; called by muse, mutect2, varscan2
- POTEE | c.763G>C p.A255P | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); called by mutect2, varscan2
- ADGRG4 | c.393C>A p.G131= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as COSV99796429; called by muse, mutect2, varscan2
- ADGRG4 | c.8583G>A p.P2861= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs377307988, COSV99796430; called by muse, mutect2, varscan2
- AL669918.1 | c.2316A>G p.R772= | Silent (SNP) | VAF 16/168 reads (10%) | catalogued as COSV101441062; called by muse, mutect2
- CLDN16 | c.699A>C p.T233= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV99290343; called by muse, mutect2, varscan2
- CRELD2 | c.1032G>A p.P344= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs143871729; called by muse, mutect2, varscan2
- DDX10 | c.1275T>A p.A425= | Silent (SNP) | VAF 91/222 reads (41%) | catalogued as COSV100489875; called by muse, mutect2, varscan2
- DSTYK | c.2250C>T p.T750= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100904687; called by muse, mutect2
- E2F5 | c.393A>G p.R131= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99809694; called by muse, varscan2
- HACD3 | c.183C>T p.F61= | Silent (SNP) | VAF 45/137 reads (33%) | catalogued as COSV99971273; called by muse, mutect2, varscan2
- LRRC7 | c.3996T>G p.V1332= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV99229193; called by muse, mutect2, varscan2
- MAP7D3 | c.1800A>G p.T600= | Silent (SNP) | VAF 34/152 reads (22%) | catalogued as COSV100286609; called by muse, mutect2, varscan2
- MXRA5 | c.621G>A p.P207= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs768082362, COSV54233892; called by muse, mutect2, varscan2
- PRDM9 | c.1257A>G p.P419= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV57012590, COSV99691063; called by muse, mutect2, varscan2
- VIPR1 | c.666C>T p.F222= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100285734; called by muse, mutect2
- WIPI1 | c.255G>C p.V85= | Silent (SNP) | VAF 66/154 reads (43%) | catalogued as COSV100048590; called by muse, mutect2, varscan2
- XXYLT1 | c.957C>T p.A319= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs371006409; called by muse, mutect2, varscan2
- YLPM1 | c.4314T>G p.S1438= | Silent (SNP) | VAF 48/100 reads (48%) | catalogued as COSV99461071; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821734 A>G | 5'Flank (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- ANAPC11 | c.110-537C>G | Intron (SNP) | VAF 15/37 reads (41%) | catalogued as COSV58712694; called by muse, mutect2, varscan2
- EIF5 | c.440-435T>G | Intron (SNP) | VAF 49/127 reads (39%) | catalogued as COSV99384991; called by muse, mutect2, varscan2
- ILF3 | c.2059+448G>C | Intron (SNP) | VAF 58/161 reads (36%) | catalogued as COSV51562490; called by muse, mutect2, varscan2
- MIR519A1 | n.56G>C | RNA (SNP) | VAF 52/86 reads (60%) | called by muse, mutect2, varscan2
- POLA1 | c.2947-21312C>T | Intron (SNP) | VAF 90/232 reads (39%) | catalogued as rs751203488; called by muse, mutect2, varscan2
